Surgical pathology report (de-identified scan), TCGA case TCGA-24-1436, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1436-01A (Primary Tumor).

[page 1 of 2]
TCGA-24-1436

Other Related Clinical Data:

DIAGNOSIS: OVARY, RIGHT, OOPHORECTOMY

- MODERATELY TO POORLY DIFFERENTIATED SEROUS PAPILLARY ADENOCARCINOMA (4.5 CM IN GREATEST DIMENSION) (SEE SYNOPSIS)
- LYMPHOVASCULAR INVASION BY CARCINOMA IS IDENTIFIED

FALLOPIAN TUBE, RIGHT SALPINGECTOMY

- SEROUS PAPILLARY ADENOCARCINOMA INVOLVING SEROSA

UTERUS, CERVIX, HYSTERECTOMY

- CHRONIC INFLAMMATION

UTERUS, ENDOMETRIUM, HYSTERECTOMY

- INACTIVE ENDOMETRIUM

UTERUS, MYOMETRIUM, HYSTERECTOMY

- LEIOMYOMAS
- FOCAL EXTENSION OF CARCINOMA INTO OUTER THIRD OF MYOMETRIUM

UTERUS, SEROSA, HYSTERECTOMY

- SEROUS PAPILLARY ADENOCARCINOMA

OMENTUM, EXCISION

- SEROUS PAPILLARY ADENOCARCINOMA

APPENDIX, EXCISION

- SEROUS PAPILLARY ADENOCARCINOMA INVOLVING THE MUSCULARIS AND SEROSA

[page 2 of 2]
[REDACTED]

[REDACTED]

Synopsis SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS 1.
PRESENT

A neoplasm is

2. The HISTOLOGIC DIAGNOSIS is: Serous adenocarcinoma
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are: Right ovary only
5. The NUCLEAR (BRODERS') GRADE of the tumor is: G3 (Poorly-differentiated)
6. Tumor IS identified on the ovarian surface(s).
- 7 Tumor DOES invade the mesovarium.
8. Tumor DOES NOT invade the adjacent fallopian tube.
9. Tumor invasion of pelvic soft tissue CANNOT BE EVALUATED.
10. Tumor involvement of the pelvic peritoneum CANNOT BE EVALUATED.
11. Metastatic involvement of the EXTRAPELVIC PERITONEUM is PRESENT.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is: 7.0 cm
14. Metastatic involvement of the uterine serosa is PRESENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases CANNOT BE EVALUATED.
17. The total number of regional lymph nodes examined is: 0
19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition	Macroscopic
T3c	IIIC	peritoneal metastasis beyond true pelvis measuring > 2 cm in greatest dimension, OR Regional lymph node metastasis OR Metastasis to capsule of liver	

20. The FINAL AJCC/UICC/FIGO STAGE IS: AJCC/UICC/FIGO
IIIC [REDACTED]

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 1a8b85ab-887e-4d70-848d-25fa846d949e (TCGA-24-1436.621D3F29-B555-4767-83DD-A6989AF0BE12.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).